Somatic mutation profile of tumor specimen TCGA-5M-AAT6-01A (aliquot TCGA-5M-AAT6-01A-11D-A40P-10) from TCGA case TCGA-5M-AAT6, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.7 years (14,852 days).
Specimen TCGA-5M-AAT6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf641d67-c3c8-4d02-902c-2ded0502aff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5M-AAT6-10A (Blood Derived Normal), aliquot TCGA-5M-AAT6-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a373792-babb-4744-a23c-eb4ee170e6de

The open-access MAF lists 2,327 somatic variants for this specimen: 1,768 protein-altering or splice-affecting, 510 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,254, Silent 510, Frame Shift Del 368, Nonsense Mutation 54, Frame Shift Ins 41, Splice Site 28, Intron 24, RNA 10, Splice Region 10, In Frame Del 6, 3'Flank 5, 3'UTR 5.

Variants (750 of 2,327; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAR | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs1064796761, COSV99426284; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.302del p.G101Afs*7 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs761606317, CM910050, CM990175; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 27/161 reads (17%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 166/468 reads (35%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL3A1 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779489, CM001093, CM001094, COSV58583545; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GCDH | c.1173dup p.N392Efs*5 | Frame Shift Ins (INS) | VAF 17/130 reads (13%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2D | c.14878C>T p.R4960* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as rs1555185969, CM111922, COSV56424402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.2533dup p.R845Pfs*3 | Frame Shift Ins (INS) | VAF 17/132 reads (13%) | catalogued as rs767415197; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/185 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LCA5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as rs781035395, CM155708, COSV63973312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.2090G>A p.C697Y | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs63750398, CM164937, CM970978, COSV99253152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.969dup p.V324Sfs*8 | Frame Shift Ins (INS) | VAF 40/251 reads (16%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, varscan2
- OTUD6B | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as rs368313959, COSV53443535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 51/287 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- SACS | c.6172del p.S2058Lfs*19 | Frame Shift Del (DEL) | VAF 13/134 reads (10%) | catalogued as rs1214399996, CD056852, CD1111485; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 24/198 reads (12%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TGM5 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749224503, CM1411736, COSV99589100; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TJP2 | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | catalogued as rs1563948951, COSV99601384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM216 | c.228del p.F76Lfs*20 (on ENST00000515837 / NM_001173990.3; = p.F15Lfs*20 on NM_016499.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | catalogued as rs767384710; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TRAPPC11 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | catalogued as rs140403642; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.15143C>T p.A5048V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.116); catalogued as rs748393788, COSV100229977; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs199544035, CM140751; called by mutect2, varscan2
- ABCA12 | c.1685T>C p.V562A (on ENST00000272895 / NM_173076.3; = p.V244A on NM_015657.3) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV99790710; called by muse, mutect2
- ABCA4 | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs554101094, COSV64672517; called by muse, mutect2, varscan2
- ABCB5 | c.2654G>A p.R885H (on ENST00000404938 / NM_001163941.2; = p.R440H on NM_178559.6) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs111647033; called by muse, mutect2, varscan2
- ABCB8 | c.1539G>T p.K513N (on ENST00000297504 / NM_001282291.2; = p.K496N on NM_007188.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874625; called by muse, mutect2, varscan2
- ABCC11 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100750921; called by muse, mutect2
- ABCC3 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs773586596, COSV99559398; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC8 | c.4608+2T>C p.X1536_splice | Splice Site (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100217439; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated, low confidence (0.16); catalogued as COSV99865465; called by muse, mutect2, varscan2
- ABI2 | c.1525A>G p.M509V (on ENST00000295851 / NM_001375719.1; = p.M471V on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV99651996; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 44/281 reads (16%) | catalogued as rs749606695; called by mutect2, varscan2
- ABRA | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747204189, COSV61731865; called by muse, mutect2
- ACACA | c.5826C>T p.S1942= | Splice Region (SNP) | VAF 16/88 reads (18%) | catalogued as rs201284070; called by muse, mutect2, varscan2
- ACADL | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1188053086, COSV99284860; called by muse, mutect2, varscan2
- ACADS | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs148588313; called by muse, mutect2, varscan2
- ACAP1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs538307560, COSV99341827; called by muse, varscan2
- ACLY | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs565573136, COSV100709760; called by muse, mutect2, varscan2
- ACOT12 | c.1384A>G p.K462E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100297028; called by muse, mutect2, varscan2
- ACP1 | c.271T>C p.C91R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); catalogued as COSV99681697; called by muse, mutect2, varscan2
- ACP7 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs1039950431, COSV58698636; called by muse, mutect2, varscan2
- ACSM3 | c.240T>G p.N80K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.855); catalogued as COSV99184687; called by muse, mutect2, varscan2
- ACTG1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555666725, COSV100111996; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAM8 | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1430410926, COSV101291685; called by muse, varscan2
- ADAMTS18 | c.3362A>G p.Y1121C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs1269874541, COSV99273375; called by muse, mutect2, varscan2
- ADARB1 | c.1069A>G p.M357V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100653948; called by muse, mutect2, varscan2
- ADCY1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs566259707, COSV52031341; called by muse, mutect2, varscan2
- ADCY2 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100603244; called by muse, mutect2, varscan2
- ADGRB1 | c.1532C>G p.T511S | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.402); catalogued as COSV100029893; called by muse, mutect2, varscan2
- ADGRB1 | c.1565A>T p.D522V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100029895; called by muse, mutect2
- ADGRB1 | c.3920T>C p.L1307P | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1454073063, COSV100029899; called by muse, mutect2, varscan2
- ADGRB2 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV99926517; called by muse, mutect2, varscan2
- ADGRE3 | c.762del p.F254Lfs*12 | Frame Shift Del (DEL) | VAF 23/147 reads (16%) | catalogued as rs762974450; called by mutect2, pindel, varscan2
- ADGRL2 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs758616029, COSV99589927; called by muse, mutect2, varscan2
- ADGRV1 | c.15859T>C p.W5287R | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs761984180, COSV101316156; called by muse, mutect2, varscan2
- ADM2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99326977; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs201936630; called by muse, mutect2, varscan2
- ADSS1 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs989698681, COSV100272321; called by muse, mutect2, varscan2
- AFP | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748956575, COSV56925987; called by muse, mutect2, varscan2
- AFTPH | c.931A>G p.S311G | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs765244594, COSV99480899; called by muse, mutect2, varscan2
- AGAP3 | c.1766C>T p.T589M (on ENST00000622464; = p.T625M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1001911325, COSV101257267; called by muse, mutect2, varscan2
- AGGF1 | c.1502A>C p.H501P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100462008; called by muse, varscan2
- AGL | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54049103, COSV99649526; called by muse, mutect2, varscan2
- AGO1 | c.973T>C p.C325R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100940872; called by muse, mutect2, varscan2
- AGPAT1 | c.510C>T p.D170= | Splice Region (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100421674; called by muse, mutect2, varscan2
- AGRN | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs752221979, COSV65068287; ClinVar: likely benign; called by muse, mutect2, varscan2
- AHCYL1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779610; called by muse, mutect2, varscan2
- AHNAK | c.11887G>A p.V3963I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs201064254, COSV57215242; called by muse, mutect2, varscan2
- AHNAK | c.5591T>C p.L1864P | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs753548490, COSV99948233; called by muse, mutect2, varscan2
- AHNAK | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as COSV99948235; called by muse, mutect2, varscan2
- AIFM1 | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV99781148; called by muse, mutect2, varscan2
- AK1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs150701679; called by muse, mutect2, varscan2
- AK5 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100481527; called by muse, mutect2, varscan2
- AKAP13 | c.7076G>A p.R2359Q (on ENST00000394518 / NM_007200.5; = p.R2363Q on NM_006738.6) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs906421680, COSV63462421; called by muse, mutect2
- AKAP3 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV99962313; called by muse, mutect2, varscan2
- AKAP8 | c.1015T>G p.S339A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as COSV99512024; called by muse, mutect2, varscan2
- AKT1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs760536822, COSV62571349; called by muse, mutect2, varscan2
- ALDH1L1 | c.734del p.F245Sfs*5 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs745759751; called by mutect2, pindel, varscan2
- ALK | c.2413A>G p.I805V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.356); catalogued as COSV101202293; called by muse, mutect2, varscan2
- ALKBH4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs544736620, COSV99479414; called by muse, mutect2, varscan2
- ALOX12B | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1231568614, COSV59875194; called by muse, mutect2, varscan2
- ALOXE3 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as rs1289470540, COSV59075557; called by muse, mutect2, varscan2
- ALPK1 | c.1814G>T p.R605M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51589258; called by muse, mutect2, varscan2
- ALPK3 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99361324; called by muse, mutect2, varscan2
- ALPK3 | c.4916G>A p.G1639D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99361326; called by muse, mutect2, varscan2
- AMMECR1L | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99761444; called by muse, mutect2, varscan2
- AMOT | c.1994G>A p.R665Q (on ENST00000371959 / NM_001113490.1; = p.R256Q on NM_133265.3) | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1289946119; called by muse, mutect2, varscan2
- ANAPC1 | c.4162C>T p.R1388* | Nonsense Mutation (SNP) | VAF 46/503 reads (9%) | catalogued as rs1241593086, COSV100594871; called by muse, mutect2, varscan2
- ANGPTL1 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs371498898; called by muse, mutect2, varscan2
- ANK3 | c.9955G>A p.D3319N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs370076710; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | catalogued as rs370637835; called by mutect2, varscan2
- ANK3 | c.7351G>A p.D2451N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs143060947, COSV55043114; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6637T>A p.F2213I | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99783748; called by muse, mutect2, varscan2
- ANKRD11 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as rs964523960, COSV99969914; called by muse, mutect2, varscan2
- ANKRD17 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100429507; called by muse, mutect2, varscan2
- ANKRD24 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs368880588, COSV53670058; called by muse, mutect2, varscan2
- ANKRD55 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100591468; called by muse, mutect2, varscan2
- ANO6 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100263495; called by muse, mutect2
- ANO9 | c.2061del p.D688Ifs*44 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | catalogued as rs1197942333; called by mutect2, pindel, varscan2
- AOC1 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs752373263, COSV100710844; called by muse, mutect2, varscan2
- AOC3 | c.2231A>C p.Q744P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100396113; called by muse, mutect2, varscan2
- AP2B1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99251395; called by muse, mutect2
- AP3D1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100642800; called by muse, mutect2, varscan2
- APBA1 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753725669, COSV55222869; called by muse, mutect2, varscan2
- APBA3 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV99516260; called by muse, mutect2, varscan2
- APC | c.4364del p.N1455Ifs*18 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | catalogued as CM080064, COSV57320740, COSV57379025; called by mutect2, pindel, varscan2
- APEX2 | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 21/176 reads (12%) | catalogued as COSV100895187; called by muse, mutect2, varscan2
- APEX2 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV100238457; called by muse, mutect2, varscan2
- APLP1 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384121; called by muse, mutect2, varscan2
- APOA2 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV57154834; called by muse, mutect2, varscan2
- APOB | c.12025G>A p.V4009M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs140424976; called by muse, mutect2, varscan2
- APOB | c.8245A>G p.T2749A | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1429563329, COSV99266420; called by muse, mutect2, varscan2
- APOB | c.1354T>A p.Y452N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266421; called by muse, mutect2, varscan2
- APOBEC3A | c.598T>C p.*200Rext*7 | Nonstop Mutation (SNP) | VAF 27/222 reads (12%) | catalogued as COSV99970364; called by muse, mutect2, varscan2
- APOBEC3D | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99329030; called by muse, mutect2, varscan2
- ARAP1 | c.4343G>A p.R1448H (on ENST00000393609 / NM_001040118.2; = p.R1203H on NM_015242.4) | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs199584464, COSV100502012, COSV61991540; called by muse, mutect2, varscan2
- ARAP3 | c.3590A>C p.E1197A | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99499948; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 20/154 reads (13%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP29 | c.2662G>T p.G888W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99558455; called by muse, mutect2
- ARHGAP31 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51793495; called by muse, mutect2, varscan2
- ARHGAP4 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs782750960, COSV63133145; called by muse, mutect2, varscan2
- ARHGEF1 | c.1121G>T p.S374I | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100529078; called by muse, mutect2, varscan2
- ARHGEF10 | c.3446C>T p.A1149V (on ENST00000398564; = p.A1124V on NM_014629.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs1464186276, COSV100034890; called by muse, mutect2
- ARHGEF17 | c.3877A>G p.M1293V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV99736033; called by muse, mutect2, varscan2
- ARHGEF18 | c.1647G>C p.E549D (on ENST00000359920 / NM_001130955.2; = p.E445D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV60468216; called by muse, mutect2, varscan2
- ARHGEF6 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs771055558, COSV99166541; called by muse, mutect2, varscan2
- ARID1B | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.395); catalogued as COSV99270267; called by muse, mutect2, varscan2
- ARMC4 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs556371991, COSV100537198, COSV59467284; called by mutect2, varscan2
- ARMCX6 | c.367T>A p.C123S | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.561); catalogued as COSV100726239; called by muse, mutect2
- ARSG | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV101477906; called by muse, mutect2, varscan2
- ARSH | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs758874207, COSV101139916; called by muse, mutect2, varscan2
- ASB7 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs774902537, COSV100234904; called by muse, mutect2, varscan2
- ASH1L | c.5377del p.H1793Ifs*7 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | catalogued as COSV64205227; called by mutect2, pindel, varscan2
- ASIC4 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.145); catalogued as rs777402491, COSV61733953; called by muse, mutect2, varscan2
- ASNSD1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs377588878; called by muse, mutect2, varscan2
- ASPM | c.10219G>A p.A3407T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV54129483, COSV99660667; called by muse, mutect2, varscan2
- ASTN2 | c.1468G>A p.D490N (on ENST00000313400 / NM_001365069.1; = p.D439N on NM_014010.5) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756643087, COSV57779489; called by muse, mutect2, varscan2
- ASXL1 | c.2453T>C p.V818A | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100039982; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 44/104 reads (42%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD3A | c.1359-1G>A p.X453_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100186428; called by muse, mutect2, varscan2
- ATG2A | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs764419673, COSV101034552; called by muse, mutect2, varscan2
- ATG9B | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV99871863; called by muse, mutect2, varscan2
- ATIC | c.1579T>C p.W527R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99377930; called by muse, mutect2, varscan2
- ATP10B | c.59T>C p.F20S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100469536; called by muse, mutect2
- ATP11A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs769716430, COSV52120087; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A1 | c.3202A>C p.S1068R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99179358; called by muse, mutect2, varscan2
- ATP13A2 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100454242; called by muse, mutect2, varscan2
- ATP13A3 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs79760253, COSV99757335; called by muse, mutect2, varscan2
- ATP2B3 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs782715889, COSV54850450; called by muse, mutect2, varscan2
- ATP2B4 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs898591806, COSV58178429; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752522705, COSV100377006, COSV57752412; called by muse, mutect2, varscan2
- ATRNL1 | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs782456237, COSV100368856, COSV58094648, COSV58105578; called by muse, mutect2
- ATXN2L | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as rs755684437, COSV100294666; called by muse, mutect2, varscan2
- B3GAT1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs750780574, COSV57000294; called by muse, mutect2, varscan2
- B4GALNT2 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV55926472; called by muse, mutect2
- B4GALNT4 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100327703; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GAT1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs1463831369, COSV100240317; called by muse, mutect2, varscan2
- B9D2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1465165250, COSV54683632; called by muse, mutect2, varscan2
- BAHCC1 | c.2329A>T p.S777C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100311807; called by muse, mutect2, varscan2
- BAHD1 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV101346774; called by muse, mutect2, varscan2
- BAK1 | c.207-1G>A p.X69_splice | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV62349440; called by muse, mutect2, varscan2
- BARHL2 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100966067; called by muse, mutect2, varscan2
- BCO2 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100730400; called by muse, mutect2
- BCOR | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1284842198, COSV100653530, COSV60706478; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 17/137 reads (12%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND4 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV101549770; called by muse, mutect2, varscan2
- BEND5 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100884137; called by muse, mutect2
- BICD2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs776528966, COSV100794170; called by muse, mutect2, varscan2
- BIN1 | c.1747G>A p.V583I (on ENST00000316724 / NM_001320642.1; = p.V444I on NM_004305.4) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs759691190, COSV52115768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMF | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs933674789, COSV99590468; called by muse, mutect2, varscan2
- BMP5 | c.1232C>A p.P411H | Missense Mutation (SNP) | VAF 64/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896095; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BNIPL | c.186A>C p.K62N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV99639694; called by muse, mutect2, varscan2
- BPIFB1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99487475; called by muse, mutect2
- BRCA2 | c.45del p.F15Lfs*10 | Frame Shift Del (DEL) | VAF 38/417 reads (9%) | catalogued as COSV100563892; called by mutect2, pindel
- BRD8 | c.3545A>G p.Y1182C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171924371, COSV99496876; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1413008697, COSV60208966; called by mutect2, varscan2
- BRWD1 | c.5367G>T p.E1789D | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100313653; called by muse, mutect2, varscan2
- BTBD11 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1176281480, COSV99775135, COSV99775590; called by muse, mutect2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 26/182 reads (14%) | catalogued as rs774921343; called by mutect2, varscan2
- BUB1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100241403; called by muse, mutect2, varscan2
- BVES | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs933501917, COSV100115009; called by muse, mutect2, varscan2
- C11orf49 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs541095717, COSV99562316, COSV99562997; called by muse, mutect2, varscan2
- C12orf42 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.141); catalogued as COSV100172398; called by muse, mutect2
- C1GALT1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1195145601, COSV99777508; called by muse, mutect2, varscan2
- C3orf70 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100621285, COSV58590311; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 24/155 reads (15%) | catalogued as rs750339990; called by mutect2, varscan2
- C8G | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56403892; called by muse, mutect2, varscan2
- CA3 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs142713454, COSV99570751; called by muse, mutect2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV61714509; called by mutect2, varscan2
- CABIN1 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV99573530; called by muse, mutect2, varscan2
- CACNA1A | c.2353A>G p.M785V | Missense Mutation (SNP) | VAF 30/1188 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100802747; called by muse, mutect2
- CACNA1H | c.5252A>G p.N1751S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99326855; called by muse, mutect2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNA2D1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62381367; called by muse, varscan2
- CACNA2D3 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV99874719; called by muse, mutect2
- CACNG3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV50070125; called by muse, mutect2, varscan2
- CADPS | c.2103+2C>T p.X701_splice | Splice Site (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99339334; called by muse, mutect2
- CADPS2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV57362583; called by muse, mutect2, varscan2
- CALR3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs756445681, COSV54171853; called by muse, mutect2, varscan2
- CAMK2B | c.1400A>G p.E467G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs773875653, COSV51668837, COSV99323603; called by muse, mutect2, varscan2
- CAMSAP1 | c.2476A>G p.N826D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100410095; called by muse, mutect2
- CAMSAP3 | c.3734G>A p.G1245D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99351194; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN9 | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV99680666; called by muse, mutect2, varscan2
- CAPS | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99222372; called by muse, varscan2
- CAPZB | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99940023; called by muse, mutect2, varscan2
- CARD10 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs762915999, COSV99325140; called by muse, mutect2, varscan2
- CARD11 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV67798697; called by muse, mutect2, varscan2
- CARD14 | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100413504; called by muse, mutect2
- CARD19 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.19); catalogued as COSV100968673; called by muse, mutect2, varscan2
- CARD6 | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs370060326; called by muse, varscan2
- CARD6 | c.2681C>A p.P894H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99620956; called by muse, mutect2, varscan2
- CARD9 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540891739, COSV59998692; called by muse, mutect2, varscan2
- CARMIL2 | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100576132; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASP5 | c.1108T>C p.W370R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99036509; called by muse, mutect2
- CAVIN2 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs1163355780, COSV100414241; called by muse, mutect2, varscan2
- CBLIF | c.255C>T p.N85= | Splice Region (SNP) | VAF 10/81 reads (12%) | catalogued as rs754251539, COSV99951007; called by muse, mutect2, varscan2
- CBY2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV60120386; called by muse, mutect2, varscan2
- CCDC22 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.417); catalogued as rs899976632, COSV100879838; called by muse, mutect2, varscan2
- CCDC33 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs749495036, COSV51498974; called by muse, mutect2, varscan2
- CCDC88A | c.4931A>G p.Q1644R (on ENST00000436346 / NM_001365480.1; = p.Q1616R on NM_018084.5) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99710700; called by muse, mutect2, varscan2
- CCDC92 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs768819776, COSV53021482; called by muse, mutect2, varscan2
- CCN4 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as COSV99137209; called by muse, mutect2, varscan2
- CCNL2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 81/555 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101275632; called by muse, mutect2, varscan2
- CCR7 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs374797000; called by muse, mutect2, varscan2
- CCZ1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 87/664 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV100382872; called by muse, mutect2, varscan2
- CD109 | c.3639C>A p.S1213R | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99753932; called by muse, mutect2, varscan2
- CD163L1 | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100550292; called by muse, mutect2, varscan2
- CD248 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); catalogued as rs202170042, COSV100256662; called by muse, mutect2, varscan2
- CD34 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV100178487; called by muse, mutect2, varscan2
- CDC25B | c.1489A>G p.M497V (on ENST00000245960 / NM_021873.3; = p.M483V on NM_004358.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99848067; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH18 | c.1701del p.I568Lfs*2 | Frame Shift Del (DEL) | VAF 19/155 reads (12%) | catalogued as COSV56946592, COSV56954100; called by mutect2, pindel, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | catalogued as rs1561075636; called by mutect2, pindel, varscan2
- CDH7 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as rs766062933, COSV59885424; called by muse, mutect2, varscan2
- CDHR5 | c.1641del p.G548Vfs*221 (on ENST00000358353 / NM_001171968.2; = p.G554Vfs*221 on NM_021924.5) | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | catalogued as rs775160782; called by mutect2, pindel, varscan2
- CDK1 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100358865; called by muse, varscan2
- CDK18 | c.808C>T p.H270Y (on ENST00000506784 / NM_212503.3; = p.H240Y on NM_002596.4) | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100774061; called by muse, mutect2, varscan2
- CDRT15 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1207148173; called by muse, mutect2
- CDT1 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99967274; called by muse, mutect2, varscan2
- CEACAM4 | c.581del p.P194Qfs*86 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as rs1555800891, COSV99701167; called by mutect2, pindel, varscan2
- CEL | c.1627C>T p.R543C (on ENST00000673714; = p.R540C on NM_001807.6) | Missense Mutation (SNP) | VAF 105/754 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs375866093; called by muse, varscan2
- CELF6 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs868080974, COSV54717433; called by muse, mutect2, varscan2
- CEMIP | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs181470477, COSV99585950; called by muse, mutect2, varscan2
- CENPE | c.5020C>G p.L1674V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV99478391; called by muse, mutect2, varscan2
- CENPF | c.4892C>T p.T1631M | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs769388025, COSV65275470; called by muse, mutect2, varscan2
- CENPP | c.519dup p.V174Cfs*5 | Frame Shift Ins (INS) | VAF 20/116 reads (17%) | catalogued as rs750494120; called by mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP131 | c.2720T>C p.L907P (on ENST00000269392 / NM_001319228.2; = p.L904P on NM_014984.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99488576; called by muse, mutect2, varscan2
- CEP192 | c.5542C>T p.R1848* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs765076361, COSV100381537, COSV58066045; called by muse, mutect2, varscan2
- CEP55 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs749800886, COSV65185876; called by muse, mutect2, varscan2
- CEP68 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.859); catalogued as COSV99561058; called by muse, mutect2, varscan2
- CERS1 | c.884A>C p.N295T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99897365; called by muse, mutect2, varscan2
- CFAP91 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs896679701, COSV56344792, COSV99847481; called by muse, mutect2, varscan2
- CFH | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100661498; called by muse, mutect2, varscan2
- CFH | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs765531414, CM1512042, COSV62776463; called by muse, mutect2, varscan2
- CGB1 | c.432del p.S145Afs*? | Frame Shift Del (DEL) | VAF 52/209 reads (25%) | catalogued as rs1487932358; called by mutect2, varscan2
- CGNL1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs375194804, COSV55568480, COSV99847817; called by muse, mutect2, varscan2
- CH25H | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.179); catalogued as COSV100897364; called by muse, mutect2, varscan2
- CHD5 | c.5396C>T p.A1799V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52407184; called by muse, mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs751094013; called by mutect2, varscan2
- CHD8 | c.6373A>G p.M2125V (on ENST00000646647 / NM_001170629.2; = p.M1846V on NM_020920.4) | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs377109513; called by muse, mutect2, varscan2
- CHD8 | c.3533G>A p.R1178H (on ENST00000646647 / NM_001170629.2; = p.R899H on NM_020920.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67870143; called by muse, mutect2, varscan2
- CHD8 | c.1424G>A p.R475H (on ENST00000646647 / NM_001170629.2; = p.R196H on NM_020920.4) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67869460; called by muse, mutect2, varscan2
- CHD9 | c.5045C>T p.S1682L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99529340; called by muse, mutect2, varscan2
- CHEK2 | c.563G>A p.R188Q (on ENST00000382580 / NM_001005735.2; = p.R145Q on NM_007194.4) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs587781667, CM030415, CM092017, COSV60421027, COSV60424422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHID1 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1177143037, COSV100059941; called by muse, mutect2, varscan2
- CHRDL1 | c.676C>T p.R226W (on ENST00000372045; = p.R232W on NM_145234.4) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs765757313, COSV54326628; called by muse, mutect2, varscan2
- CHRM1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs753639928, COSV61007115; called by mutect2, varscan2
- CHRM5 | c.1469T>A p.V490D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101271982; called by muse, mutect2, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs753250273; called by mutect2, varscan2
- CHST11 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs147660307; called by muse, varscan2
- CHST15 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100655207; called by muse, mutect2, varscan2
- CHST3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs1402502581, COSV64150428; called by muse, mutect2, varscan2
- CIITA | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV60861616; called by muse, mutect2, varscan2
- CLASP2 | c.2209A>T p.S737C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100223744; called by muse, varscan2
- CLCN2 | c.2068del p.E690Rfs*6 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs765672654; called by mutect2, pindel, varscan2
- CLCN4 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101073900; called by muse, mutect2, varscan2
- CLCN6 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765674820, COSV100412031; called by muse, mutect2, varscan2
- CLCN6 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1440077965, COSV56739950; called by muse, mutect2, varscan2
- CLCN7 | c.1966T>C p.S656P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV99247417; called by muse, mutect2
- CLCNKB | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.619); catalogued as COSV100990292; called by muse, mutect2
- CLIP3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.193); catalogued as rs772399672, COSV100859337; called by muse, mutect2, varscan2
- CLIP4 | c.1185del p.D396Ifs*19 | Frame Shift Del (DEL) | VAF 60/314 reads (19%) | catalogued as rs1332364476; called by mutect2, varscan2
- CLK3 | c.605G>A p.R202H (on ENST00000395066 / NM_001130028.1; = p.R54H on NM_003992.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs780907715, COSV61414550; called by muse, mutect2, varscan2
- CLMP | c.505A>C p.I169L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs141141774; called by muse, mutect2, varscan2
- CLPB | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99578291; called by muse, mutect2, varscan2
- CLSPN | c.2402C>A p.P801H | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99231140; called by muse, mutect2, varscan2
- CLTCL1 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs781910321, COSV99595344; called by muse, mutect2, varscan2
- CMPK2 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99878918; called by muse, mutect2, varscan2
- CNGB1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs377240706; called by muse, mutect2, varscan2
- CNN2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99566158; called by muse, mutect2, varscan2
- CNOT4 | c.964G>A p.A322T (on ENST00000315544 / NM_001190848.1; = p.A319T on NM_013316.4) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV100211826; called by muse, mutect2, varscan2
- CNTN2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765367852, COSV59352562; called by muse, mutect2, varscan2
- CNTN4 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 42/368 reads (11%) | catalogued as rs1399339293, COSV100638994; called by muse, mutect2, varscan2
- COG1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 45/329 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs772435977, COSV100245367; called by muse, mutect2, varscan2
- COG4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs758395513, COSV60424803; called by muse, varscan2
- COG6 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs780630711, COSV62995228; called by muse, mutect2, varscan2
- COL19A1 | c.2258del p.G753Afs*32 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as COSV59566859; called by mutect2, pindel, varscan2
- COL1A1 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99867610; called by muse, mutect2, varscan2
- COL1A2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.15); catalogued as COSV99800274; called by muse, mutect2, varscan2
- COL27A1 | c.2836-2A>G p.X946_splice | Splice Site (SNP) | VAF 26/166 reads (16%) | catalogued as COSV100621082; called by muse, mutect2, varscan2
- COL27A1 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs138913107; called by muse, mutect2, varscan2
- COL4A2 | c.2414del p.P805Lfs*15 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | catalogued as rs1324194272; called by mutect2, pindel, varscan2
- CPE | c.1113+2T>C p.X371_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV68581330; called by muse, mutect2, varscan2
- CPNE7 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs141048497, COSV99254948; called by muse, mutect2, varscan2
- CPQ | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767885584, COSV99613021; called by muse, mutect2, varscan2
- CR1L | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54323109; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRACD | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs745793025, COSV99949551; called by muse, mutect2, varscan2
- CREB3L4 | c.1127T>C p.M376T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs764666056, COSV99665772; called by muse, mutect2, varscan2
- CREBBP | c.6628C>T p.Q2210* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99270708; called by muse, mutect2, varscan2
- CREBBP | c.4985A>G p.D1662G | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99270711; called by muse, mutect2, varscan2
- CREBZF | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as rs770349667, COSV99476360; called by muse, mutect2, varscan2
- CRHR2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100530076; called by muse, mutect2, varscan2
- CROCC | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs762565818, COSV65011398; called by mutect2, varscan2
- CROCC | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779341603, COSV100978299; called by muse, mutect2, varscan2
- CRYM | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as rs754271922, COSV99561844; called by muse, mutect2
- CSPG5 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV99273917; called by muse, mutect2, varscan2
- CT55 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); catalogued as COSV99358918; called by muse, mutect2, varscan2
- CTC1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs753797185, COSV58983930; called by muse, mutect2, varscan2
- CTDP1 | c.2748-2A>G p.X916_splice | Splice Site (SNP) | VAF 39/300 reads (13%) | catalogued as COSV99310802; called by muse, mutect2, varscan2
- CTNNA1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100243014, COSV57074244; called by muse, mutect2, varscan2
- CTNNA2 | c.1925T>C p.F642S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100561290; called by muse, mutect2, varscan2
- CTR9 | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 46/319 reads (14%) | catalogued as COSV63728658; called by muse, mutect2, varscan2
- CTSZ | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748740856, COSV99413648; called by muse, mutect2, varscan2
- CUL3 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024409; called by muse, mutect2, varscan2
- CXXC1 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99496620; called by muse, mutect2, varscan2
- CYP1A2 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 15/134 reads (11%) | catalogued as COSV59660038; called by muse, mutect2, varscan2
- CYP2A13 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57840348; called by muse, mutect2, varscan2
- CYP3A4 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100315739; called by muse, mutect2, varscan2
- CYP4Z1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100497795; called by muse, mutect2
- CYRIA | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100838469; called by muse, mutect2, varscan2
- CYTH4 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as COSV99958025; called by muse, mutect2, varscan2
- DAAM1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181718144, COSV62834102; called by mutect2, varscan2
- DACH2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs757022695, COSV64176887; called by muse, mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 24/177 reads (14%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAGLA | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99944510; called by muse, mutect2
- DAPK2 | c.677del p.P226Lfs*17 | Frame Shift Del (DEL) | VAF 25/142 reads (18%) | catalogued as COSV56048539; called by mutect2, pindel, varscan2
- DCAF11 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.048); catalogued as rs1448316083, COSV100386734; called by muse, mutect2, varscan2
- DCAF12 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761820325, COSV63511516; called by muse, mutect2, varscan2
- DCAF12L1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180607542, COSV64422079; called by muse, mutect2, varscan2
- DCAF7 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1301213649, COSV100177688, COSV60408816; called by muse, mutect2, varscan2
- DCC | c.3751A>G p.I1251V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.852); catalogued as COSV101473297; called by muse, mutect2, varscan2
- DCDC1 | c.959A>G p.K320R | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV100663740; called by muse, mutect2, varscan2
- DCHS1 | c.6413C>A p.P2138Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100202223; called by muse, mutect2, varscan2
- DCLRE1B | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100849811; called by muse, mutect2, varscan2
- DDX52 | c.268del p.R90Gfs*4 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as rs1482330308; called by mutect2, pindel, varscan2
- DEAF1 | c.1442G>A p.S481N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV100102159; called by muse, mutect2, varscan2
- DEDD2 | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV100260296; called by muse, mutect2, varscan2
- DEFB127 | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101213849; called by muse, mutect2, varscan2
- DENND1A | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs775924786, COSV101012112, COSV65348181, COSV65348851; called by muse, mutect2, varscan2
- DENND2B | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs763434311, COSV58202652, COSV58207614; called by muse, mutect2, varscan2
- DES | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as rs57965306, CM051448, COSV100900475, COSV64660407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKZ | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100642057; called by muse, mutect2, varscan2
- DHRS3 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100879646; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 36/186 reads (19%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX15 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100391503; called by muse, mutect2, varscan2
- DHX29 | c.2980T>C p.Y994H | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99287438; called by muse, mutect2, varscan2
- DHX37 | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs754186165, COSV100439321; called by muse, mutect2, varscan2
- DIAPH3 | c.3266G>A p.R1089Q (on ENST00000400324 / NM_001042517.2; = p.R826Q on NM_030932.3) | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs759456145; called by muse, mutect2, varscan2
- DIAPH3 | c.3142C>T p.R1048C (on ENST00000400324 / NM_001042517.2; = p.R785C on NM_030932.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs200684775; called by muse, mutect2, varscan2
- DICER1 | c.2851T>C p.Y951H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as COSV100602237; called by muse, mutect2, varscan2
- DICER1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1555371642, COSV58626673, COSV58629101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.1299T>A p.N433K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV100602240; called by muse, mutect2, varscan2
- DIDO1 | c.6118C>T p.R2040C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV56628215; called by muse, mutect2
- DIP2B | c.2065G>T p.A689S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs775762047, COSV99998804; called by muse, mutect2, varscan2
- DIP2B | c.4483G>A p.V1495M | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749017384, COSV56589395, COSV99998807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.835); catalogued as rs767613451, COSV99451393; called by muse, mutect2, varscan2
- DISP3 | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759999426, COSV53824552; called by muse, mutect2, varscan2
- DLGAP2 | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs377468058; called by muse, mutect2, varscan2
- DMXL2 | c.5359A>G p.S1787G | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99196601; called by muse, mutect2, varscan2
- DNAH1 | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562192705, COSV101325836; called by muse, mutect2, varscan2
- DNAH11 | c.7975G>A p.G2659S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100179686; called by muse, mutect2, varscan2
- DNAH17 | c.8183A>C p.K2728T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as COSV101102747; called by muse, mutect2
- DNAH17 | c.6950C>T p.P2317L | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs371579556; called by muse, mutect2, varscan2
- DNAH3 | c.7727G>A p.R2576H | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs544149586, COSV54533843; called by muse, mutect2, varscan2
- DNAH5 | c.10658G>A p.R3553Q | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs144393366, COSV99448734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.10562C>T p.T3521M | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759725771, COSV56767431; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAI2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs754901875; called by muse, mutect2, varscan2
- DNAJC1 | c.629del p.N210Mfs*5 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs767116339; called by pindel, varscan2
- DNAJC11 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748496570, COSV99275781; called by muse, mutect2, varscan2
- DNAJC28 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100074738; called by muse, mutect2, varscan2
- DNAJC9 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99654796; called by muse, mutect2, varscan2
- DNM3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs373493204; called by muse, mutect2, varscan2
- DNMBP | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs755577741, COSV60621755, COSV60633571; called by muse, mutect2, varscan2
- DNMT3A | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.874); catalogued as rs139293773, COSV53036512, COSV53049625, COSV53069747; called by muse, mutect2, varscan2
- DOCK1 | c.3848A>G p.Y1283C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1276490876, COSV54753968; called by muse, mutect2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.1643G>T p.R548M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99371047; called by muse, mutect2, varscan2
- DOCK8 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs147287319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK9 | c.3530A>T p.Q1177L (on ENST00000376460 / NM_001366676.2; = p.Q1178L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1234517202, COSV100239821; called by muse, mutect2, varscan2
- DOK1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99284117; called by muse, mutect2, varscan2
- DOP1A | c.4904C>T p.T1635I | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99382264; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | catalogued as rs750520568; called by mutect2, varscan2
- DPH2 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV99356532; called by muse, mutect2, varscan2
- DPP9 | c.344C>T p.T115M (on ENST00000598800; = p.T144M on NM_139159.5) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs994294799, COSV53594978; called by muse, mutect2, varscan2
- DPY19L2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752764341, COSV100116846; called by muse, mutect2, varscan2
- DRC1 | c.2173T>C p.S725P | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV99718145; called by muse, mutect2, varscan2
- DRD3 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs201369546, COSV55678948; called by muse, mutect2, varscan2
- DRP2 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1239457122, COSV67871831; called by muse, mutect2, varscan2
- DSG1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99936205; called by muse, mutect2, varscan2
- DST | c.16495A>G p.I5499V (on ENST00000361203 / NM_001374722.1; = p.I3087V on NM_015548.5) | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs748675779, COSV99757746; called by muse, mutect2, varscan2
- DUOX2 | c.3631C>T p.R1211C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374410986, CM159749; called by muse, mutect2
- DVL1 | c.1324G>A p.A442T (on ENST00000378888 / NM_001330311.2; = p.A417T on NM_004421.3) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs766432002, COSV100229643; called by muse, mutect2, varscan2
- DVL2 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99138598; called by muse, mutect2, varscan2
- DYNC1H1 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV100795086; called by muse, mutect2, varscan2
- DYNC1H1 | c.9655C>T p.R3219C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1555411141, COSV64139496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E4F1 | c.415+2T>C p.X139_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100065864; called by muse, mutect2, varscan2
- ECM1 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100682099; called by muse, mutect2, varscan2
- EFCAB11 | c.240A>T p.L80F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV99965699; called by muse, mutect2
- EFEMP2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100337286; called by muse, mutect2, varscan2
- EGFL8 | c.432C>T p.D144= | Splice Region (SNP) | VAF 14/99 reads (14%) | catalogued as rs767779638, COSV61248884; called by muse, mutect2, varscan2
- EGR1 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV99525495; called by muse, mutect2, varscan2
- EHD1 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277151; called by muse, mutect2, varscan2
- EHF | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99140969; called by muse, mutect2, varscan2
- EIF2AK3 | c.3293C>T p.S1098L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs770232594, COSV57546895; called by muse, mutect2
- EIF3D | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs771000513, COSV99341627; called by muse, mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 33/318 reads (10%) | catalogued as rs1554600455; called by pindel, varscan2
- EIF4G1 | c.4034C>T p.T1345I (on ENST00000346169 / NM_198241.3; = p.T1150I on NM_004953.5) | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59994598; called by muse, mutect2, varscan2
- ELAVL3 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs749068597, COSV100820804; called by muse, mutect2, varscan2
- ELF2 | c.791T>G p.M264R (on ENST00000379550 / NM_001331036.2; = p.M204R on NM_006874.4) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99643033; called by muse, mutect2, varscan2
- ELF4 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100257441; called by muse, mutect2, varscan2
- ELK3 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); catalogued as rs1064000, COSV99957692; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 51/234 reads (22%) | catalogued as rs766700925; called by mutect2, varscan2
- EMCN | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV99598488; called by muse, mutect2
- EMG1 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99781147; called by muse, mutect2, varscan2
- EML3 | c.2531G>A p.S844N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV99604374; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as rs770453803; called by mutect2, varscan2
- ENG | c.277del p.R93Efs*9 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as CD052103, CM000009, COSV100785364; called by mutect2, pindel, varscan2
- ENOX2 | c.423G>T p.E141D (on ENST00000338144 / NM_001382520.1; = p.E112D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV100584316; called by muse, mutect2, varscan2
- ENPEP | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1304122286, COSV54450989; called by muse, mutect2, varscan2
- ENPP2 | c.1120A>G p.S374G (on ENST00000075322 / NM_001040092.3; = p.S426G on NM_006209.5) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1484228542, COSV99308698; called by muse, mutect2
- EPB41 | c.2119C>T p.R707C (on ENST00000343067 / NM_001166005.2; = p.R465C on NM_004437.4) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772607266, COSV100548956, COSV58050079; called by muse, mutect2, varscan2
- EPB41L1 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs747135476, COSV99151187; called by muse, mutect2, varscan2
- EPB41L4A | c.1577del p.N526Tfs*46 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs755555590; called by mutect2, pindel, varscan2
- EPB42 | c.698C>T p.T233I (on ENST00000441366 / NM_001114134.2; = p.T263I on NM_000119.3) | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV100282041; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- EPHX1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs371279887, COSV99689078; called by muse, mutect2, varscan2
- ERICH6 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV55802504; called by muse, mutect2, varscan2
- ERVFRD-1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs140934168; called by muse, mutect2, varscan2
- ESYT3 | c.2481del p.F827Lfs*7 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | catalogued as rs772672190; called by mutect2, pindel, varscan2
- EVI5 | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100945394; called by muse, mutect2, varscan2
- EVPL | c.6020G>A p.G2007D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1244504203, COSV100044746; called by muse, mutect2, varscan2
- EXOC3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs764412645, COSV100155417; called by muse, mutect2, varscan2
- EXPH5 | c.4577A>G p.D1526G | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99761834; called by muse, mutect2
- EZR | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61455971; called by muse, mutect2, varscan2
- F3 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100474325; called by muse, mutect2, varscan2
- FAM110C | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100566892; called by muse, mutect2, varscan2
- FAM120A | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99465965; called by muse, mutect2, varscan2
- FAM122C | c.268_271del p.N90Efs*15 | Frame Shift Del (DEL) | VAF 50/420 reads (12%) | catalogued as rs1315749652; called by pindel, varscan2
- FAM126B | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as rs765005916; called by muse, mutect2, varscan2
- FAM135A | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.885); catalogued as COSV99526082; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM214A | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV55926326; called by muse, mutect2, varscan2
- FAM214A | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV99958123; called by muse, mutect2, varscan2
- FAM214A | c.323A>C p.E108A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99958125; called by muse, mutect2
- FAM53A | c.135C>T p.N45= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as rs781743881, COSV100357146; called by muse, mutect2, varscan2
- FAM83H | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.103); catalogued as rs1554622013, COSV100567969; called by muse, mutect2, varscan2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | catalogued as rs746983128; called by mutect2, varscan2
- FARS2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as rs746837108, COSV51175680; called by muse, mutect2, varscan2
- FAS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as CM132740, COSV58239725, COSV58239851; called by muse, mutect2, varscan2
- FASN | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs758221850, COSV100148001; called by mutect2, varscan2
- FASN | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs377076774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.13264A>G p.T4422A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1248948388, COSV101499438; called by muse, mutect2, varscan2
- FBN1 | c.8155A>G p.K2719E | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100355685; called by muse, mutect2, varscan2
- FBN1 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100355686; called by muse, mutect2, varscan2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as rs748600284, COSV99331968; called by mutect2, varscan2
- FBN3 | c.6295G>A p.V2099I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1290016682, COSV54464251, COSV99561273; called by muse, mutect2, varscan2
- FBP2 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547312807, COSV64695230; called by muse, mutect2, varscan2
- FBP2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768188420; called by muse, mutect2, varscan2
- FBXL20 | c.1163A>C p.D388A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99234407; called by muse, mutect2, varscan2
- FBXO34 | c.2131T>C p.Y711H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100572030; called by muse, mutect2, varscan2
- FBXW9 | c.1256T>C p.V419A (on ENST00000587955; = p.V399A on NM_032301.3) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100982036; called by muse, mutect2, varscan2
- FCSK | c.2473G>A p.G825S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241387284, COSV99851021; called by muse, mutect2, varscan2
- FEM1C | c.1814T>C p.I605T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99174388; called by muse, mutect2, varscan2
- FGD4 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV99847300; called by muse, mutect2, varscan2
- FGD6 | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59698027; called by muse, mutect2, varscan2
- FHOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99264260; called by muse, mutect2, varscan2
- FHOD1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs766104962, COSV99264265; called by muse, mutect2, varscan2
- FKBP15 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.411); catalogued as rs748316719, COSV99439190; called by muse, mutect2, varscan2
- FKBP6 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99334115; called by muse, mutect2, varscan2
- FLNA | c.3208-2A>G p.X1070_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100774874; called by muse, mutect2
- FLNB | c.7561G>A p.G2521R | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913797, COSV99915541; called by muse, mutect2, varscan2
- FLNC | c.6049G>A p.V2017M | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1019545678, COSV100368458, COSV57966956; called by muse, mutect2, varscan2
- FLRT2 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs190071329, COSV58147992; called by muse, mutect2, varscan2
- FLT4 | c.3712G>A p.G1238R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs766960409, COSV99987652, COSV99988399; called by muse, mutect2, varscan2
- FLT4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV56097004; called by muse, mutect2, varscan2
- FLVCR2 | c.1151T>C p.M384T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99471375; called by muse, mutect2, varscan2
- FMN2 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100145964; called by muse, varscan2
- FN3K | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100333324; called by muse, mutect2, varscan2
- FNDC3A | c.2206C>T p.R736C (on ENST00000492622 / NM_001079673.2; = p.R680C on NM_014923.5) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs771506910, COSV101256812, COSV68132196; called by mutect2, varscan2
- FNDC3B | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs770426040, COSV61038134, COSV61042953; called by muse, mutect2, varscan2
- FOCAD | c.2056-2A>C p.X686_splice | Splice Site (SNP) | VAF 30/212 reads (14%) | catalogued as COSV100620532; called by muse, mutect2, varscan2
- FOXE1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as COSV100909947; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs760347049; called by mutect2, varscan2
- FOXQ1 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs770819384, COSV57259274; called by muse, mutect2, varscan2
- FRAS1 | c.10609C>T p.R3537C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs779521854, COSV99353583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV101084883; called by muse, mutect2, varscan2
- FRMPD3 | c.3950C>A p.P1317H | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99346595; called by muse, mutect2, varscan2
- FRS2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as rs1048144608, COSV54729019; called by muse, mutect2, varscan2
- FRY | c.6828+2T>C p.X2276_splice | Splice Site (SNP) | VAF 12/139 reads (9%) | catalogued as COSV100969494; called by muse, mutect2
- FUOM | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99529450; called by muse, mutect2, varscan2
- FZD10 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99969495; called by muse, mutect2, varscan2
- FZD3 | c.1533del p.H512Mfs*8 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | catalogued as rs1563404339; called by mutect2, pindel, varscan2
- FZD6 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as COSV62471184; called by muse, mutect2
- G3BP1 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100663990; called by muse, varscan2
- GALK1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99849457; called by muse, mutect2
- GALNT14 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100204031; called by muse, mutect2, varscan2
- GAMT | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 114/620 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99362208; called by muse, varscan2
- GANAB | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1294139471, COSV60467946; called by muse, mutect2
- GAS2L1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs376278123; called by muse, mutect2, varscan2
- GAS7 | c.1376T>G p.L459R (on ENST00000432992 / NM_201433.2; = p.L319R on NM_003644.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100096046; called by muse, mutect2, varscan2
- GATA3 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV60517934; called by muse, mutect2
- GATA5 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367777789; called by muse, mutect2, varscan2
- GBF1 | c.1739A>G p.D580G (on ENST00000369983 / NM_001377137.1; = p.D579G on NM_004193.3) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100890553; called by muse, mutect2
- GBX1 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99880944; called by muse, mutect2, varscan2
- GCK | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs762922697, CM032905, COSV61753463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCLC | c.1043T>C p.I348T (on ENST00000643939; = p.I346T on NM_001498.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.273); catalogued as COSV99988720; called by muse, mutect2, varscan2
- GCNT4 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100466530; called by muse, mutect2, varscan2
- GDF3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145849916, COSV61712909; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs771881138; called by mutect2, varscan2
- GJA3 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV99576420; called by muse, mutect2
- GLG1 | c.2575T>C p.C859R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215970; called by muse, mutect2, varscan2
- GLI2 | c.2953G>A p.A985T (on ENST00000361492 / NM_001374353.1; = p.A1002T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1206309646, COSV100083597; called by muse, mutect2, varscan2
- GLI2 | c.3275G>T p.R1092M (on ENST00000361492 / NM_001374353.1; = p.R1109M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100082269; called by muse, mutect2, varscan2
- GLI4 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs768383740, COSV60682405; called by muse, mutect2, varscan2
- GLIS3 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100174329; called by muse, mutect2, varscan2
- GLRA3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as rs749930503, COSV56862956, COSV56867677; called by muse, mutect2, varscan2
- GNAI2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs781986131, COSV99807097; called by muse, mutect2, varscan2
- GNE | c.394C>T p.R132C (on ENST00000396594 / NM_001128227.3; = p.R101C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs148523065, CM128143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | catalogued as rs370114090; called by mutect2, varscan2
- GP6 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1282834493, COSV59977494; called by muse, mutect2, varscan2
- GPER1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs779447108, COSV99867179; called by muse, mutect2, varscan2
- GPR119 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 29/164 reads (18%) | catalogued as rs771380953, COSV52276324; called by muse, varscan2
- GPR119 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs201128715, COSV99358673; called by muse, varscan2
- GPR135 | c.1380G>T p.W460C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1346439980, COSV101229329; called by muse, mutect2, varscan2
- GPR179 | c.1378G>A p.V460I (on ENST00000621958; = p.V459I on NM_001004334.4) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs769384383; called by muse, mutect2
- GPRASP2 | c.1185del p.E396Rfs*68 | Frame Shift Del (DEL) | VAF 22/187 reads (12%) | catalogued as rs773649162; called by mutect2, pindel, varscan2
- GPSM2 | c.1265T>C p.V422A | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs571651862, COSV99915390; called by muse, mutect2, varscan2
- GPT | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99477694; called by muse, mutect2, varscan2
- GRAMD4 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV100730558; called by muse, mutect2, varscan2
- GRIK2 | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV59729741; called by muse, mutect2
- GRIK3 | c.1058A>G p.H353R | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100902152; called by muse, mutect2, varscan2
- GRIN1 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); catalogued as rs1185667771, COSV100160457; called by muse, mutect2, varscan2
- GRIN3A | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100701617; called by muse, mutect2, varscan2
- GRK5 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770147450, COSV100963124; called by muse, mutect2, varscan2
- GRM3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV64467861; called by muse, mutect2, varscan2
- GRM4 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs377004554, COSV99055663; called by muse, mutect2, varscan2
- GRM4 | c.1663T>C p.Y555H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100946467; called by muse, mutect2, varscan2
- GRM4 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.997); catalogued as rs1006772500, COSV65219435; called by muse, mutect2, varscan2
- GRM6 | c.2497G>A p.G833S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs373757775, COSV99179682, COSV99179733; called by muse, mutect2, varscan2
- GRWD1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037527529, COSV99474355; called by muse, mutect2, varscan2
- GTPBP2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769723702, COSV100200037, COSV100200048; called by muse, mutect2, varscan2
- GTSE1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV101483225; called by muse, mutect2, varscan2
- GUCY2D | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs1274312758, COSV99644086; called by muse, mutect2, varscan2
- H3-5 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100461695; called by muse, mutect2, varscan2
- HAPLN3 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs777163714, COSV100613805; called by muse, mutect2, varscan2
- HAUS7 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100444211; called by muse, mutect2, varscan2
- HBS1L | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774407298, COSV63200137; called by muse, mutect2
- HCFC2 | c.1231+2T>C p.X411_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV57560656; called by muse, mutect2, varscan2
- HCN1 | c.2455G>A p.V819M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1197215604, COSV57493912; called by muse, mutect2, varscan2
- HEATR1 | c.5178G>T p.E1726D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100857696; called by muse, mutect2, varscan2
- HECTD3 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as rs369161641; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HECW1 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV101223925; called by muse, mutect2, varscan2
- HECW2 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778764644, COSV99647693; called by muse, mutect2, varscan2
- HELZ | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1452667914, COSV62379535; called by muse, mutect2, varscan2
- HERC1 | c.6935_6937del p.G2312del | In Frame Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs932955902; called by pindel, varscan2
- HERC2 | c.11965C>T p.Q3989* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99874954; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HGFAC | c.693del p.F231Lfs*16 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | catalogued as rs111368413; called by mutect2, pindel, varscan2
- HIBADH | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99607281; called by muse, mutect2, varscan2
- HIC1 | c.1691C>T p.A564V (on ENST00000322941 / NM_001098202.1; = p.A545V on NM_006497.4) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53967575; called by muse, mutect2, varscan2
- HID1 | c.2318del p.P773Lfs*8 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as COSV60913992; called by mutect2, pindel, varscan2
- HIF3A | c.1642del p.R548Gfs*2 (on ENST00000377670 / NM_152795.4; = p.R479Gfs*2 on NM_022462.4) | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as COSV52202176; called by mutect2, pindel, varscan2
- HIRA | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99600574; called by muse, mutect2, varscan2
- HIVEP2 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772259068, COSV99174142; called by mutect2, varscan2
- HMCN1 | c.268+1G>A p.X90_splice | Splice Site (SNP) | VAF 16/143 reads (11%) | catalogued as COSV99631389; called by muse, mutect2, varscan2
- HMCN1 | c.16711A>G p.M5571V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1299679218, COSV99631391; called by muse, mutect2, varscan2
- HMOX2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17880805; called by muse, mutect2, varscan2
- HOXD4 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100106913, COSV60459563; called by muse, mutect2, varscan2
- HPS5 | c.1087C>T p.R363C (on ENST00000349215 / NM_181507.2; = p.R249C on NM_007216.4) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150200184; called by muse, mutect2, varscan2
- HROB | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99809289; called by muse, mutect2, varscan2
- HROB | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749144204, COSV99809290; called by muse, mutect2, varscan2
- HS6ST3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747297518, COSV65017001; called by muse, mutect2, varscan2
- HSCB | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs768337799, COSV99319728; called by muse, mutect2, varscan2
- HSD17B6 | c.736+1G>A p.X246_splice | Splice Site (SNP) | VAF 17/123 reads (14%) | catalogued as rs1274159325, COSV100444377; called by muse, mutect2, varscan2
- HSPG2 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575688004, COSV101020821; called by muse, mutect2, varscan2
- HTRA3 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911002159, COSV56469370; called by muse, mutect2, varscan2
- HVCN1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs779165493, COSV54373885; called by muse, mutect2, varscan2
- HYAL2 | c.1245G>A p.W415* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | catalogued as COSV100753920; called by muse, mutect2, varscan2
- ICE1 | c.1426A>G p.R476G | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99665067; called by muse, mutect2, varscan2
- IDE | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 31/220 reads (14%) | catalogued as COSV56422927; called by muse, mutect2, varscan2
- IFT172 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs984586780, COSV99562754; called by muse, mutect2, varscan2
- IFT22 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100190095; called by muse, mutect2, varscan2
- IFT43 | c.410A>G p.N137S (on ENST00000314067 / NM_001102564.3; = p.N142S on NM_052873.3) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as rs753110306, COSV99466320; called by muse, mutect2, varscan2
- IFT43 | c.482T>C p.L161P (on ENST00000314067 / NM_001102564.3; = p.L166P on NM_052873.3) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99466324; called by muse, mutect2, varscan2
- IFT80 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs140972476, COSV58447811; called by muse, mutect2, varscan2
- IGF2R | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100807671; called by muse, mutect2, varscan2
- IGLV3-25 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs775465989; called by muse, mutect2
- IGSF1 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 29/189 reads (15%) | catalogued as COSV100812175; called by muse, mutect2, varscan2
- IGSF3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as rs530464588, COSV100604886; called by muse, mutect2, varscan2
- IGSF3 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217790157, COSV100604888; called by muse, mutect2, varscan2
- IKZF4 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100009192; called by muse, mutect2
- IL17RD | c.1282T>C p.Y428H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as rs750856460, COSV99577516; called by muse, mutect2, varscan2
- IL1RL1 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99294242; called by muse, mutect2
- IL20RA | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV100360051; called by muse, mutect2, varscan2
- IL7R | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 204/1376 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100286390; called by muse, mutect2, varscan2
- INPP5F | c.2231T>C p.I744T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1466307835, COSV100740234; called by muse, mutect2, varscan2
- INSM1 | c.422del p.G141Afs*95 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs1386949548; called by mutect2, varscan2
- INTS1 | c.3863A>G p.H1288R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.594); catalogued as COSV101248086; called by muse, mutect2, varscan2
- IPO4 | c.1067T>C p.M356T | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99938133; called by muse, mutect2
- IQCN | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV100828326; called by muse, mutect2, varscan2
- IQGAP2 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs537445542, COSV57171445; called by muse, mutect2, varscan2
- IRF7 | c.1541A>C p.Q514P (on ENST00000397566; = p.Q501P on NM_001572.5) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99209807; called by muse, mutect2, varscan2
- IRGQ | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100338189; called by muse, mutect2, varscan2
- IRS2 | c.3410G>A p.R1137H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65478036; called by muse, mutect2, varscan2
- IRS4 | c.3415G>A p.A1139T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100929612; called by muse, mutect2, varscan2
- IRS4 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV64534967; called by muse, mutect2, varscan2
- ISY1 | c.541+1G>A p.X181_splice | Splice Site (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99860730, COSV99860886; called by muse, mutect2, varscan2
- ITCH | c.1735G>A p.V579M (on ENST00000262650 / NM_001257137.3; = p.V538M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99392718; called by muse, mutect2, varscan2
- ITGA10 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs782383906, COSV65196264; called by muse, mutect2, varscan2
- ITGA10 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100994963; called by muse, mutect2, varscan2
- ITGA10 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100994962; called by muse, mutect2, varscan2
- ITGA3 | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759928378, COSV99143804; called by muse, mutect2, varscan2
- ITGA3 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs757614915, COSV50313795, COSV99143808; called by muse, mutect2, varscan2
- ITGA8 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150974250; called by muse, mutect2, varscan2
- ITGB1 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171783; called by muse, mutect2, varscan2
- ITPR3 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs747619884, COSV100967605; called by muse, mutect2, varscan2
- ITPR3 | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs767435428, COSV100967606; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as rs1555369773; called by mutect2, pindel, varscan2
- JAKMIP3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs747360916, COSV53819314; called by muse, mutect2
- JMJD7-PLA2G4B | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760597072, COSV59826591; called by muse, mutect2, varscan2
- KANSL3 | c.2087C>T p.T696I (on ENST00000666923 / NM_001349262.2; = p.T670I on NM_001115016.3) | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as rs1450529347, COSV100831193; called by muse, mutect2, varscan2
- KAT6A | c.2653A>G p.K885E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.014); catalogued as COSV99705409; called by muse, mutect2, varscan2
- KCNA10 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.265); catalogued as COSV100871448; called by muse, mutect2, varscan2
- KCNB2 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV101578863; called by muse, mutect2
- KCNC3 | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.677); catalogued as rs1178457532, COSV100979296; called by muse, mutect2, varscan2
- KCNE3 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV100035653; called by muse, mutect2, varscan2
- KCNE5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1455260841, COSV64508587; called by muse, mutect2, varscan2
- KCNH4 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.165); catalogued as rs1488706304, COSV99237495; called by muse, mutect2, varscan2
- KCNJ14 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770440037, COSV100655785; called by muse, mutect2, varscan2
- KCNN1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99716109; called by mutect2, varscan2
- KCNQ2 | c.1408G>A p.D470N (on ENST00000359125 / NM_172107.4; = p.D442N on NM_004518.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.616); catalogued as rs751907059, COSV100610360; called by muse, mutect2, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2, varscan2
- KCNV2 | c.1405C>A p.L469M | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD082142, COSV101172620; called by muse, mutect2, varscan2
- KCTD13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV100442175; called by muse, mutect2, varscan2
- KDM5B | c.3194A>G p.E1065G | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.407); catalogued as COSV52503587; called by muse, mutect2, varscan2
- KDM5B | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs375547145; called by muse, mutect2, varscan2
- KHDRBS1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100306233; called by muse, mutect2, varscan2
- KIAA1109 | c.7718G>A p.R2573H | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52675317; called by muse, mutect2, varscan2
- KIAA1217 | c.1697T>C p.M566T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100286862; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel
- KIDINS220 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99875971; called by muse, mutect2, varscan2
- KIF17 | c.1358A>T p.E453V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99929293; called by muse, mutect2, varscan2
- KIF18A | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588850; called by muse, mutect2, varscan2
- KIF18B | c.1178del p.G393Efs*91 (on ENST00000593135 / NM_001265577.2; = p.G393Efs*103 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs1347932473, COSV59271974, COSV59272099; called by mutect2, pindel, varscan2
- KIF25 | c.1081C>T p.R361W (on ENST00000354419 / NM_030615.2; = p.R309W on NM_005355.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs374321260; called by muse, mutect2, varscan2
- KIF26B | c.6064G>A p.E2022K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100832796; called by muse, mutect2, varscan2
- KIF3B | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996404; called by muse, mutect2
- KIF4A | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 85/589 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100979573; called by muse, mutect2, varscan2
- KIF5B | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100192055; called by muse, mutect2, varscan2
- KIF5C | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV101276160; called by muse, mutect2, varscan2
- KIFAP3 | c.607del p.C203Vfs*22 | Frame Shift Del (DEL) | VAF 34/204 reads (17%) | catalogued as rs1380692252; called by mutect2, varscan2
- KIFC2 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768022702, COSV100023876; called by muse, mutect2, varscan2
- KLF4 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); catalogued as rs751611404, COSV101012707; called by muse, mutect2, varscan2
- KLHDC8A | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as rs768279570, COSV100903772; called by muse, mutect2
- KLHL10 | c.1115T>C p.M372T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99509567; called by muse, mutect2
- KLHL12 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100935950; called by muse, mutect2, varscan2
- KLHL20 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99268490; called by muse, mutect2, varscan2
- KLHL31 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100911805; called by muse, mutect2, varscan2
- KLHL34 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 29/180 reads (16%) | catalogued as COSV65280276; called by muse, mutect2, varscan2
- KLHL36 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs368978011; called by muse, varscan2
- KMT2A | c.4678G>A p.A1560T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs1388016179, COSV63285193; called by muse, mutect2, varscan2
- KMT2B | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1336661633, COSV99719958; called by muse, mutect2, varscan2
- KMT2C | c.12098C>T p.P4033L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.727); catalogued as rs776094080, COSV51529332; called by mutect2, varscan2
- KMT2E | c.2810T>C p.V937A | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV99996543; called by muse, mutect2
- KMT5C | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1422483879, COSV99726233; called by muse, mutect2, varscan2
- KRT10 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779748369, COSV54089279; called by muse, mutect2, varscan2
- KRT37 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs151232863, COSV99845594; called by muse, mutect2, varscan2
- KRT37 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs201044349, COSV56657382; called by muse, mutect2, varscan2
- KRT6C | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99360060; called by muse, mutect2, varscan2
- KRT74 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV99977573; called by muse, mutect2, varscan2
- KRT74 | c.580T>A p.Y194N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99977574; called by muse, mutect2, varscan2
- KRT77 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527167; called by muse, mutect2, varscan2
- KRT81 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100576993; called by muse, mutect2
- KRT85 | c.956A>C p.E319A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1200511473, COSV99225555; called by muse, mutect2, varscan2
- KRT85 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as COSV99225339; called by muse, mutect2, varscan2
- KRTAP1-3 | c.366del p.C123Afs*4 | Frame Shift Del (DEL) | VAF 28/222 reads (13%) | catalogued as rs1366715174; called by mutect2, varscan2
- KRTAP10-6 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs781859260, COSV100554354; called by muse, varscan2
- KRTAP11-1 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV60095466; called by muse, mutect2, varscan2
- KRTAP12-1 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs200130684, COSV59969601; called by muse, mutect2, varscan2
- KRTAP13-1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV62663184; called by muse, mutect2, varscan2
- KRTAP4-2 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376498383, COSV100894548; called by muse, mutect2, varscan2
- LAMA1 | c.4469G>T p.R1490M | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101056861, COSV67536373; called by muse, mutect2, varscan2
- LAMA3 | c.4759G>A p.V1587M | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs776186644, COSV99335225; called by mutect2, varscan2
- LAMA3 | c.5203C>T p.P1735S (on ENST00000313654 / NM_198129.4; = p.P126S on NM_000227.6) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1438135261, COSV52538636, COSV99335227; called by muse, mutect2, varscan2
- LAMA4 | c.1385G>A p.R462Q (on ENST00000230538 / NM_001105206.3; = p.R455Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs781977997, COSV100038761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.7653G>A p.A2551= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as rs753551909, COSV53373080, COSV99440897; called by muse, mutect2, varscan2
- LAMB2 | c.4093C>T p.R1365W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751854328, COSV59732648; called by muse, mutect2, varscan2
- LAMC1 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs142883085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LANCL2 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99634911; called by muse, mutect2, varscan2
- LAPTM4A | c.525del p.F175Lfs*5 | Frame Shift Del (DEL) | VAF 57/385 reads (15%) | catalogued as rs1476796878; called by mutect2, pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBP | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs374882159; called by mutect2, varscan2
- LCOR | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV99616992; called by muse, mutect2, varscan2
- LDHAL6B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as rs759880084, COSV55684108; called by muse, mutect2, varscan2
- LDLRAD4 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63334421; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 35/244 reads (14%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LEFTY1 | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686563; called by muse, mutect2, varscan2
- LENG8 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs368841946; called by muse, mutect2, varscan2
- LGALS9 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 75/750 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs534643765, COSV100119488; called by muse, mutect2, varscan2
- LGI4 | c.869del p.G290Afs*180 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as rs778360981; called by pindel, varscan2
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LHFPL6 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549287054, COSV65445598; called by muse, mutect2
- LIG1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs376771010; called by muse, varscan2
- LINC02210-CRHR1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749376023, COSV99523827; called by mutect2, varscan2
- LINGO1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as COSV62438828; called by muse, mutect2, varscan2
- LINGO2 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as rs756489081, COSV58061284; called by muse, mutect2, varscan2
- LLGL1 | c.2549C>T p.T850M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753689203, COSV57498258; called by muse, mutect2, varscan2
- LMBRD2 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99682991; called by mutect2, varscan2
- LMF2 | c.460del p.Q154Rfs*34 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | catalogued as rs1422118645; called by mutect2, pindel, varscan2
- LMO7 | c.1653del p.D552Mfs*3 (on ENST00000357063; = p.D282Mfs*3 on NM_015842.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as COSV58533691; called by mutect2, pindel, varscan2
- LMO7 | c.2015T>G p.L672R (on ENST00000357063; = p.L402R on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.929); catalogued as COSV100413502; called by muse, mutect2, varscan2
- LMTK3 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99540738; called by muse, mutect2
- LONRF2 | c.1340T>G p.F447C | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101110983; called by muse, mutect2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LPCAT1 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99359118; called by muse, mutect2, varscan2
1,577 further variants in this file (1,018 protein-altering or splice-affecting, 510 silent, 49 other) are not listed here.
